Somatic mutation profile of tumor specimen TCGA-V4-A9E5-01A (aliquot TCGA-V4-A9E5-01A-11D-A39W-08) from TCGA case TCGA-V4-A9E5, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Choroid; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 51.9 years (18,948 days).
Specimen TCGA-V4-A9E5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6add08a-355e-47cf-90e1-63562c092f17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V4-A9E5-10A (Blood Derived Normal), aliquot TCGA-V4-A9E5-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b08b406d-6064-4885-ac78-8138b31037df

The open-access MAF lists 14 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Frame Shift Del 1, 3'Flank 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAQ | c.626A>C p.Q209P | Missense Mutation (SNP) | VAF 21/67 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121913492, COSV54105903, COSV54105914, COSV54108414; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.1997A>C p.K666T | Missense Mutation (SNP) | VAF 29/62 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs374250186, COSV59205833, COSV59206062, COSV59207657; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- DLL1 | c.894C>A p.C298* | Nonsense Mutation (SNP) | VAF 30/47 reads (64%) | catalogued as COSV64537345; called by muse, mutect2, varscan2
- FAT4 | c.11570C>T p.A3857V | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.07); catalogued as rs536513777, COSV58680265; called by muse, mutect2, varscan2
- FCGR2A | c.895G>T p.D299Y (on ENST00000271450 / NM_001136219.3; = p.D298Y on NM_021642.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV54839604; called by muse, mutect2, varscan2
- LRRC66 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as COSV58633372; called by muse, mutect2, varscan2
- ZAN | c.940C>T p.R314W | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as rs764974438, COSV61808414; called by muse, mutect2, varscan2
- GJA5 | c.260_270del p.T87Sfs*132 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- TFAP2B | c.830C>T p.S277L | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GPR101 | c.342C>T p.F114= | Silent (SNP) | VAF 14/22 reads (64%) | catalogued as rs200302047; called by muse, mutect2, varscan2
- TSC22D3 | c.145C>A p.R49= | Silent (SNP) | VAF 55/92 reads (60%) | catalogued as COSV59777565; called by muse, mutect2, varscan2
- UBR5 | c.6396T>C p.T2132= | Silent (SNP) | VAF 54/163 reads (33%) | catalogued as rs777572603; called by muse, mutect2, varscan2
- SNX18 | chr5:54543372 A>G | 3'Flank (SNP) | VAF 10/49 reads (20%) | called by muse, mutect2, varscan2
- SSX5 | c.69+210G>C | Intron (SNP) | VAF 31/102 reads (30%) | called by muse, mutect2, varscan2
